Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A680, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A680-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 1
SEX: F

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Paraganglioma and paraesophageal hernia. Operative Procedure/Tissue Submitted:
Exploratory laparotomy, resection of periaortic mass, open cholecystectomy,
open paraesophageal hernia repair.

PROCEDURE: SPGD

VERIFIED BY:

1. "Retroperitoneal mass." Received in formalin in a medium container is a 6.8 x 5.9 x 4.5 cm, lobular, well-encapsulated mass. Sectioning reveals yellow-orange, solid cut surfaces remarkable for scattered calcifications, diffuse hemorrhage and central areas of fibrosis. No areas of necrosis are identified grossly. Note: The mass is encapsulated within a thickened, fibrotic sheath. (6 cassettes)
2. "Right portal lymph node." Received in formalin in a small container is a 1.2 x 0.9 x 0.6 cm possible lymph node with attached adipose tissue. Bisected. (1 cassette)
3. "Gallbladder." Received in formalin in a medium container is a 7.6 x 4.5 x 1.4 cm gallbladder. The serosal surfaces are remarkable for a 0.6 cm, transmural defect located within the fundus. Upon opening, the mucosa is diffusely green-yellow and trabeculated in appearance. In addition, the walls are diffusely thickened, up to 0.8 cm. The lumen contains green, viscous bile. No masses, calculi or any other abnormalities are noted. (1 cassette)

PROCEDURE: SPDX

VERIFIED BY:

1. Soft tissue of retroperitoneum, excision: Paraganglioma (6.8 cm).
2. Right portal lymph node, excision: One benign lymph node, negative for neoplasm (0/1).
3. Gallbladder, resection: Fibrous adhesions, no other histologic abnormality.

I, _____, the signing staff pathologist, have personally
examined and interpreted the slides from this case.

Source: NCI Genomic Data Commons file 91e15242-6bec-437c-b544-1755c5a38f7f (TCGA-RW-A680.08E19DE1-EF43-4DF4-B80A-AB9263D5C4AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).